TCGA case TCGA-G6-A8L7 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1d37becb-7a1f-4d04-a0d1-bb14192b56f6

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 81 years; Vital status: Alive.

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 81.8 years (29,883 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC clinical M: MX; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Tumor grade: G3; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 2.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Basal cell carcinoma, nodular: ICD-O-3 morphology code: 8097/3; Tissue or organ of origin: Nasal cavity; Classification of tumor: Prior primary; Age at diagnosis: 77.7 years (28,397 days); Days to diagnosis: -1,486 days (-4.1 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,408 days (-3.9 years); Treatment anatomic sites: Skin.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,727 days (4.7 years); Disease response: Tumor Free.
- Days to follow up: 2,133 days (5.8 years); Disease response: Tumor Free.
- Karnofsky performance status: 80; ECOG performance status: 1; Timepoint: Other.

Molecular and laboratory tests
- Leukocytes: Normal.
- Hemoglobin: Low.
- Calcium: Low.
- Platelets: Normal.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 40; Tobacco smoking onset year: 1965; Tobacco smoking quit year: 2005.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G6-A8L7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 190 mg.
  Slide TCGA-G6-A8L7-01A-01-TSA: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 30; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-G6-A8L7-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G6-A8L7-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Serum calcium level: Low; Hemoglobin level: Low; Lymph nodes examined: Yes; Tobacco smoking history indicator: 4; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome at TCGA followup: Complete Remission/Response; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy histological type: Nodular and Micronodular Basal Cell Carcinoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Mohs Micrographic Surgery with advanced closure.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,133 days; disease-specific survival: no event (censored), 2,133 days; disease-free interval: no event (censored), 2,133 days; progression-free interval: no event (censored), 2,133 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-G6-A8L7-01A-11D-A36W-01): tumor purity 0.49, ploidy 1.89, whole-genome doublings 0.
